Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABKU, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABKU-TTP2-A (Primary Tumor).

Material: A N2 lymph node of lower pulmonary ligament
B N1 lymph nodes
C Medium lobe
D N2 right paratracheal lymph node
E N2 subcarinal lymph nodes

Macro Description: A) 0.5 cm lymph node. B) 2 irregular fragments, 2.5 cm and 1 cm, containing 4 lymph nodes. C) 10.5x9x4cm pulmonary lobe that 2.5 cm from the bronchial resection margin presents a 3.3 max diameter neof ormation constituted of hard, whitish tissue that retracts the visceral pleura. C1) bronchial resection margin. C2) 3 peribronchial lymph nodes C3-C8) Samples of the neoplasia in relation to the India ink stained visceral pleura. C9) Normal parenchyma. D) 1.1 cm lymph node. E) Two 1.5 cm lymph nodes.

Micro Description: A)B)D)E) N2 lymph nodes of the lower pulmonary ligament, N1 (lymph node), N2 right paratracheal (lymph nodes), and N2 subcarinal (lymph nodes) all free of neoplasia.
C) G2 adenocarcinoma not infiltrating the pleura, peribronchial lymph nodes and bronchial resection margin free of neoplasia; remaining parenchyma site of areas of emphysema and atelectasis.
pT1, pN0. Medium lobectomy and lymphadenectomy.

Stage: T1N0 G2

Report 2:
Date Report 2:

CDDP-YP-ABKU-01-PR

Material 2:

Macro Description 2:

Notes: Report printed from computer

ICDO Code: 81403

ICDO Description: Adenocarcinoma, NOS

Status: OK

Other Info:

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: Lung, NOS C34.9

ICD-10

C34.90

hw 2/10/16

Source: NCI Genomic Data Commons file 707ba7f4-379d-4213-8fed-4a4803846d13 (CDDP-ABKU-TTP2.49654E68-B6A7-4935-ABCC-CEF70B2C608A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).